Surgical pathology report (de-identified scan), TCGA case TCGA-24-1567, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1567-01A (Primary Tumor).

[page 1 of 4]
24 - 1567

Other Related Clinical Data:

DIAGNOSIS: OVARIES, RIGHT AND LEFT, BILATERAL SALPINGO-OOPHORECTOMY

- POORLY DIFFERENTIATED ADENOCARCINOMA, MIXED PAPILLARY SEROUS AND ENDOMETRIOID TYPES
- SEE COMMENT AND SYNOPSIS

FALLOPIAN TUBES, RIGHT AND LEFT, BILATERAL SALPINGO-OOPHORECTOMY

- METASTATIC POORLY DIFFERENTIATED ADENOCARCINOMA

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY

- ENDOCERVICAL POLYP

UTERUS, ENDOMETRIUM, HYSTERECTOMY

- PROLIFERATIVE PHASE

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- NO HISTOPATHOLOGIC ABNORMALITY

LYMPH NODE, LEFT EXTERNAL ILIAC, EXCISION

- NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE

LYMPH NODE, GASTROCOLIC OMENTUM, EXCISION

- NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE

SOFT TISSUE, GASTROCOLIC OMENTUM, BIOPSY

- METASTATIC POORLY DIFFERENTIATED ADENOCARCINOMA

OMENTUM, EXCISION

- METASTATIC POORLY DIFFERENTIATED ADENOCARCINOMA

[page 2 of 4]
[REDACTED]

[REDACTED] By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By [REDACTED]**

Intraoperative Consultation: An intraoperative non-microscopic consultation was obtained and interpreted as: "8.5 x 8.5 x 6.5 cm ovary with solid and focally cystic lesion comprising the majority of tissue. Attached 4.5 cm long fallopian tube. Portion of ovarian tissue frozen. Portion for Tumor Bank. The rest for permanents." [REDACTED]

FS1: Left adnexa - "Adenocarcinoma consistent with Mullerian origin," [REDACTED]

[REDACTED] Microscopic Description and Comment: Sections of both the right and left ovaries show poorly differentiated adenocarcinoma, mixed papillary serous and endometrioid types. The papillary serous areas form well developed papillary structures lined by epithelium with a very high nuclear grade, and psammoma bodies are easily identified. The areas of endometrioid carcinoma show regions of solid growth and also have a high nuclear grade; of particular note, focally the areas of endometrioid carcinoma show squamous differentiation, and within these areas, there are microscopic foci in which tumor invades the ovarian parenchyma with the morphology of a poorly differentiated, keratinizing squamous cell carcinoma (slide A1). Tumor is diffusely present on the surface of both ovaries. Tumor extends to the adjacent fallopian tubes, and the lumen of the right tube is focally effaced by adenocarcinoma.

Sections of the uterus show no evidence of metastatic poorly differentiated adenocarcinoma. The cervix contains an endocervical polyp, the endometrium is proliferative, and the myometrium is unremarkable. There is no evidence of metastatic adenocarcinoma on the serosal surface of the uterus.

There is no evidence of metastatic adenocarcinoma in the single left external iliac lymph node. In addition, we note that there is no evidence of metastatic adenocarcinoma in one incidental lymph node identified in sections from the gastrocolic omentum specimen.

Microscopic foci of metastatic poorly differentiated adenocarcinoma are present within the fat of the gastrocolic omentum specimen, as are numerous foci of metastatic poorly differentiated adenocarcinoma in the omentectomy specimen (where the nodules are all less than 2 cm in greatest dimension). [REDACTED]

[REDACTED]

History: The patient is a [REDACTED] with left pelvic mass. Operative procedure: Exploratory lap, [REDACTED] radical tumor debulking, omentectomy, left external iliac node biopsy. Clinical diagnosis: Left adnexal mass.

Specimen(s) Received:

- A: OVARY, TUMOR
- B: UTERUS, CERVIX
- C: LYMPH NODE
- D: OMENTUM, ROUTINE
- E: OMENTUM, ROUTINE

Gross Description The specimen is received in five containers of formalin, each labeled with the patient's name. The first container is additionally labeled "left adnexal" [REDACTED] The specimen is an enlarged ovary consistent with dimensions listed in the non-microscopic intraoperative consultation weighing 260 grams. The specimen has been previously incised at

[page 3 of 4]
[REDACTED]

time of frozen section analysis to reveal a predominantly solid tan tumor with cystic areas. Some of the cysts contain yellow mucoid-like material. Several foci of tumor is present on the serosal surface of the ovary. The attached fallopian tube is of normal caliber (up to 0.6 cm diameter) and contains a small 0.7 cm paratubal cyst. No gross tumor directly involves the fallopian tube, however, a 0.6 cm nodule of solid tissue is present in the surrounding soft tissue. Labeled A1, solid area tumor with surface involvement; A2, solid area tumor with adjacent cystic areas; A3, solid area of tumor; A4, solid area of tumor penetrating serosa with large serosal nodule; A5, A6, additional sections of tumor; A7, fallopian tube and paratubal cyst; A8, fallopian tube and possible tumor in para fallopian tube soft tissue; A9, tissue frozen as FS1. [REDACTED]

The second container is labeled "uterus, cervix, RSO." The specimen is a 140 gram, 8 x 8 x 4.5 x 4.0 cm uterus with an attached 2.7 x 2.4 x 1.5 cm ovary and a 7.0 x 1.0 cm fallopian tube. The cervix measures 4.0 x 3.5 x 3.5 cm with a 1.0 x 0.9 cm endocervical polyp. The outer ectocervix is unremarkable. The endometrial cavity measures 3.2 x 2.0 cm and contains light tan homogenous endometrium without focal abnormalities. Uterine myometrium is unremarkable and the uterine serosa is smooth without nodules or other irregularities. The right ovary contains a 1.2 x 1.1 x 0.7 cm solid nodule on the serosal surface. Cut section of the ovary contains a 1.6 x 1.1 x 1.1 cm ovarian cyst with a thickened wall measuring 0.7 cm suspicious for tumor. The center of the cyst has papillary projections. Cut sections of the fallopian tube reveal focal areas where the lumen is obliterated by a solid mass of tissue grossly suspicious for tumor. Labeled B1, anterior cervix and endocervix; B2, lower uterine segment and lower uterus; B3, endometrium, myometrium and anterior serosa; B4, posterior cervix and endocervix; B5, posterior lower uterine segment and lower uterine wall; B6, posterior endometrium, myometrium and serosa; B7, fallopian tube; B8, right ovary with small papillary cyst and surface tumor; B9, area of cyst with solid area. [REDACTED]

The third container is additionally labeled "L external iliac LN," and contains a single piece of yellow adipose tissue with a small lymph node measuring 0.5 cm in greatest dimension. [REDACTED]

The fourth container is labeled "gastrocolic omentum," and contains an aggregate of yellow adipose tissue measuring 3.5 x 2.5 x 0.7 cm. Two small tan nodules are present within the adipose tissue. [REDACTED]

The fifth container is also labeled "omentectomy." It contains a 15 x 5.5 x 2.0 cm aggregate of lobulated fat. Several ill-defined solid areas are present within the omental fat. The largest measures approximately 2 cm in dimension, which on cut section contain streaks of white fibrous tissue interdigitating among the adipose tissue. No definite nodular masses are identified. [REDACTED]

[REDACTED]

Synopsis SYNOPSIS REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS 1. PRESENT

A neoplasm is

2. The HISTOLOGIC DIAGNOSIS is:

Poorly differentiated adenocarcinoma, mixed papillary serous and endometrioid types

3. The LOCATION OF THE PRIMARY TUMOR is: Right and left ovary

4 and 5. The NUCLEAR (BRODERS') GRADE of the tumor is: G3 (Poorly-differentiated)

[page 4 of 4]
6. Tumor IS identified on the ovarian surfaces.
7. Tumor DOES invade the mesovarium.
8. Tumor DOES invade the adjacent fallopian tube.
9. Metastatic involvement of the EXTRAPELVIC PERITONEUM cannot be evaluated.
10. Metastatic involvement of the omentum is PRESENT.
11. The maximum dimension of tumor implants outside the true pelvis is 4 cm
12. Metastatic involvement of the uterine serosa is ABSENT.
13. Metastatic involvement of the endometrium is ABSENT.
14. Regional lymph node metastases are ABSENT.
15. The total number of lymph nodes examined is 2.
16. Extranodal extension by tumor is NOT APPLICABLE; no nodal metastases are present.
17. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is classified as:

TNM Scheme	FIGO Scheme	Definition
T3b	IIIB	Macroscopic
peritoneal metastasis beyond true pelvis with		
dimension		no implant measuring > 2 cm in greatest

18. THE REGIONAL LYMPH NODES are classified as: N0 (Nodes are free of metastases)
19. THE STATUS OF DISTANT TUMOR SITES is classified as: MX (Status cannot be assessed)
20. The FINAL AJCC/UICC/FIGO STAGE IS: IIIB (T3b/N0/MX)

Source: NCI Genomic Data Commons file f4c93988-18d1-46b2-8f3f-75f652fd6a8a (TCGA-24-1567.90910BBC-49E1-495B-9B06-11056FF401DF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).